Surgical pathology report (de-identified scan), TCGA case TCGA-AO-A12D, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site MSKCC, specimen TCGA-AO-A12D-01A (Primary Tumor).

[page 1 of 5]
Clinical Diagnosis & History:
Core biopsy of left breast shows infiltrating carcinoma with FNA of node positive for carcinoma. Right mastectomy is prophylactic.

- 1: SP: Right breast
- 2: SP: Left breast and axillary contents levels 1 and 2
- 3: SP: Sentinel node #1 level 1 right axilla
- 4: SP: Additional left breast upper flap tissue

1) BREAST, RIGHT; PROPHYLACTIC MASTECTOMY:
- BENIGN BREAST TISSUE WITH FLORID SCLEROSING ADENOSIS, FOCAL DUCTAL HYPERPLASIA WITHOUT ATYPIA, SECRETORY CHANGES, CYSTS, FIBROADENOMATOID CHANGES AND A FEW MICROCALCIFICATIONS.
- UNREMARKABLE NIPPLE.

2) BREAST AND AXILLARY CONTENTS LEVELS 1 AND 2, LEFT; MODIFIED RADICAL MASTECTOMY AND AXILLARY LYMPH NODE DISSECTION:
- INVASIVE DUCTAL CARCINOMA, HISTOLOGIC GRADE II-III/III, NUCLEAR GRADE III/III, ASSOCIATED WITH LYMPHOCYTIC INFILTRATE AND MEASURING 1.9 CM IN LARGEST DIMENSION MICROSCOPICALLY.
- A MINOR COMPONENT OF DUCTAL CARCINOMA IN SITU (DCIS), SOLID AND MICROPAPILLARY TYPES WITH HIGH NUCLEAR GRADE AND NECROSIS, IS PRESENT ADMIXED WITH AND AWAY FROM THE INVASIVE CARCINOMA.
- NO INVOLVEMENT OF THE NIPPLE, SKIN OR THE SURGICAL MARGINS BY CARCINOMA IS IDENTIFIED.
- LYMPHOVASCULAR INVASION IS PRESENT.
- THE NON-NEOPLASTIC BREAST TISSUE SHOWS PREVIOUS BIOPSY SITE CHANGES, FLORID SCLEROSING ADENOSIS, DUCTAL HYPERPLASIA WITHOUT ATYPIA AND A BENIGN INTRADUCTAL PAPILLOMA.
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF POSITIVE LYMPH NODES IN RELATION TO THE TOTAL NUMBER OF LYMPH NODES EXAMINED):
LEVEL I: 0/8
LEVEL II: 1/7
THERE IS FOCAL EXTRANODAL EXTENSION OF CARCINOMA (>2 MM) AND PERINODAL VASCULAR INVASION.
- RESULTS OF SPECIAL STAINS (ER, PR, HER-2/NEU) WILL BE REPORTED AS AN ADDENDUM.

** Continued on next page **

1CB-0-3
carcinoma, infiltrating duct, NOS 8500/3
Site: breast, NOS 850.9 pw 10/23/11

[illegible]

UUD:9363D53D-BC3B-4AC0-8185-536C6DB3A6AE

[page 2 of 5]
- 3) LYMPH NODE, SENTINEL #1 LEVEL 1 RIGHT AXILLA; BIOPSY:
- ONE BENIGN LYMPH NODE (0/1).
- ADDITIONAL H/E LEVELS AND CYTOKERATIN (AE1:AE3) IMMUNOSTAINS ARE ALSO
NEGATIVE FOR METASTATIC TUMOR.
- 4) SOFT TISSUE, ADDITIONAL LEFT BREAST UPPER FLAP; EXCISION:
- ADIPOSE TISSUE, NEGATIVE FOR TUMOR.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	ER-C	
	PR-C	
	HER2-C	
	NEG-HER2	
	NEG CONT	
	IMM RECUT	
	ER-C	
	PR-C	
	ER-C	
	PR-C	
	HER2-C	
	NEG-HER2	
	NEG CONT	
	IMM RECUT	
	AE1:AE3	
	NEG CONT	
	IMM RECUT	

Gross Description:

1) The specimen is received fresh, labeled "Right breast. Stitch marks axillary tail". It consists of a breast measuring 18 x 17 x 5 cm overlaid by white-tan skin, measuring 10 x 4.5 cm. There is a centrally placed, slightly inverted nipple, measuring 1.2 cm in diameter, surrounded by an unremarkable areola, measuring 4 cm in diameter. Cross-sectioning of the specimen reveals dense fibroid tissue in the central portion of the specimen, but no discrete mass is identified. Representative sections are taken.

Summary of Sections:

N - Nipple
NB - Nipple base
DM - Deep margin

** Continued on next page **

[page 3 of 5]
FT - Fibroadipose tissue
LIQ - Lower inner quadrant
LOQ - Lower outer quadrant
UIQ - Upper inner quadrant
UOQ - Upper outer quadrant

Page 3 of 3

3

2) The specimen is received fresh, labeled "Left breast and axillary contents, levels 1 and 2 (2 specimen tags attached)". It consists of a breast measuring 16 x 16 x 5.5 cm, with an axillary tail measuring 10 x 7 x 1.6 cm. The axillary tail has 2 tags designating levels 1 and 2. The specimen is overlaid by white-tan, unremarkable skin, measuring 10.5 x 1.3 cm. The is a centrally placed, everted nipple, measuring 1.0 cm in diameter, surrounded by unremarkable areola, measuring 4 cm in diameter. Cross-sectioning of the specimen reveals a firm to hard, fairly circumscribed, centrally placed mass, measuring 1.7 x 1.5 x 1.5 cm, approximately 1.0 cm from the deep margin. The mass, arbitrarily designated T1 is surrounded by dense fibrous tissue. Approximately 5 cm lateral and 3 cm anterior to T1 is a mass measuring 1.0 cm in diameter and approximately 4 cm from the deep margin. The second mass, which is arbitrarily designated T2, has a central cavity filled with necrotic material grossly. The remainder of the breast tissue consists of unremarkable fibroadipose tissue. Examination of the axillary tail show several lymph nodes at level 1, ranging from 0.5 cm to 2.0 cm and at level 2 ranging from 0.5 cm to 2.5 cm. The smaller lymph nodes are submitted in toto. The largest lymph nodes are bisected, alternatively inked and submitted entirely.

Summary of Sections:

N - Nipple
NB - Nipple base
FT - Fibrous tissue
DM - Deep margin
T1 - Centrally-placed mass, 1 cm to the deep margin
T2 - Laterally-placed mass
LIQ - Lower inner quadrant
LOQ - Lower outer quadrant
UIQ - Upper inner quadrant
UOQ - Upper outer quadrant
LN1 - Level 1 lymph node
BLN1 - Bisected level 1 lymph node
BLLN1 - Bisected largest level 1 lymph node
LN2 - Level 2 lymph node
BLN2 - Bisected level 2 lymph node
BLLN2 - Bisected largest level 2 lymph node

3) The specimen is received in formalin, labeled "Sentinel node #1, level 1, right axilla". It consists of an apparent lymph node, measuring 1.2 x 1.0 x 0.5 cm, surrounded by pink-tan, unremarkable adipose tissue, measuring 1.0 x 1.0 x 0.2 cm. The lymph node is bisected and submitted in toto, in addition to the surrounding fibroadipose tissue.

Summary of Sections:

** Continued on next page **

[page 4 of 5]
4) The specimen is received in formalin, labeled "Additional left breast upper flap tissue". It consists of yellow-tan fibroadipose tissue, measuring 4 x 3 x 0.5 cm. Cross-sectioning of the specimen reveals grossly unremarkable adipose tissue. The specimen is entirely submitted.

Summary of Sections:

FA - Fibroadipose tissue

Summary of Sections:

Part 1: SP: Right breast

Block	Sect. Site	PCs
1	dm	1
8	fa	8
1	liq	1
1	loq	1
1	n	1
1	nb	1
1	uiq	1
1	uoq	1

Part 2: SP: Left breast and axillary contents levels 1 and 2

Block	Sect. Site	PCs
1	bl1n1	1
2	bl1n2	2
1	bln1	1
2	bln2	2
1	dm	1
2	fa	2
1	liq	1
2	ln1	2
1	ln2	1
1	loq	1
1	n	1
3	nb	1
2	t1	3
1	t2	2
1	uiq	1
1	uoq	1

Part 3: SP: Sentinel node #1 level 1 right axilla

Block	Sect. Site	PCs
1	sln	1

** Continued on next page **

[page 5 of 5]
Part 4: SP: Additional left breast upper flap tissue Page 5 of 5

Block 5 Sect. Site fa PCs 5

Procedures/Addenda:

Addendum

Date Ordered:

Date Complete:

Date Reported:

Status: Signed Out

By:

Addendum Diagnosis

ADDENDUM REPORT

SITE: LEFT BREAST (PART #2)

ER: 0% NUCLEAR STAINING

PR: 0% NUCLEAR STAINING

HER-2/NEU (HERCEPTEST): POSITIVE (STAINING INTENSITY OF 3+)

CONTROLS ARE SATISFACTORY

** End of Report **

Source: NCI Genomic Data Commons file 1aad23a2-4546-4993-bef3-402632965429 (TCGA-AO-A12D.9363D53D-BC3B-4AC0-8185-536C6DB3A6AE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).